Gene-level copy-number profile of tumor specimen TCGA-24-1843-01A from TCGA case TCGA-24-1843, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.0 years (24,469 days).
Specimen TCGA-24-1843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e2790b61-5daa-40de-85fa-763cb86fcfc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1843-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8470415a-769b-4fa1-a85a-5e41349ab94d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 759; copy number 2: 23,506; copy number 3: 27,796; copy number 4: 5,563; copy number 5: 1,579; copy number 6: 290; copy number 7: 55; copy number 9: 3; copy number 10: 23; copy number 11: 195; copy number 19: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1843-01A-01D-0577-01): tumor purity 0.77, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 327 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,858,659–169,038,416, 5 genes, copy number 10: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr4:118,850,688–119,061,247, 2 genes, copy number 7 (within-gene range 3–7): SYNPO2, AC096745.1.
- chr6:30,600,413–30,900,156, 25 genes, copy number 7: PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640.
- chr6:151,404,762–152,129,619, 9 genes, copy number 7: RMND1, HSPA8P15, ARMT1, CCDC170, RNU6-813P, ESR1, AL356311.1, AL078582.2, AL078582.1.
- chr6:161,347,417–162,727,775, 3 genes, copy number 7 (within-gene range 4–8): PRKN, AL132982.1, AL138716.1.
- chr11:69,294,151–69,367,726, 2 genes, copy number 9 (within-gene range 3–9): MYEOV, IFITM9P.
- chr19:11,987,617–12,078,106, 2 genes, copy number 7–11 (within-gene range 6–11): ZNF433-AS1, AC008770.4.
- chr19:12,014,732–12,580,975, 42 genes, copy number 11 (within-gene range 7–11): ZNF433, AC008770.1, RNA5SP465, ZNF878, ZNF844, RNA5SP466, AC022415.2, Y_RNA, ZNF788P, ZNF20, RSL24D1P8, RNA5SP467, ZNF625-ZNF20, AC022415.1, ZNF625, ZNF136, AC012618.3, ZNF44, AC012618.1, AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2.
- chr19:27,638,483–32,676,597, 94 genes, copy number 7–19 (within-gene range 4–19) (broad region; genes not listed).
- chr19:33,386,950–33,521,791, 1 gene, copy number 9 (within-gene range 4–9): PEPD.
- chr19:36,687,612–39,631,446, 142 genes, copy number 11 (within-gene range 1–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 759. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
